Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EN-01A (Primary Tumor).

Department of Cancer Pathology

ICD-O-3
Carcinoma, squamous cell
non-keratinizing 8072/3
Site Buccal mucosa 106.D
W 5/24/13

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: **Surgery and Laryngological Oncology Dept.**

Physician in charge:

Clinical diagnosis (suspicion) **Tumour of the left cheek - Ca planoepitheliale G3 exulcerans.**

Date of admission:

Material:

- 1) Material: mucous membrane. Please examine the marked margin. Method of collection: Lesion resection.

Histopathological diagnosis

Examination performed on:

Invasive non-keratinising squamous cell carcinoma.
G3, pT2 (8070/3 T-51030)*

* codes according to ICD-O-3 or SNOMED

Microscopic description:

Invasive non-keratinising squamous cell carcinoma.

Margin marked with two wires infiltrated by cancer, other margins uninvolved. Signs of vascular invasion, no signs of nerve invasion.

Assistant:

Pathologist:

Preliminary result:

Edited by:

Examination performed on:

Non-keratinising squamous cell carcinoma G3.

Final reply to be given after full material is developed

Assistant:

Pathologist:

Results of intraoperative examination:

Examination performed on:

Cancer invasion on the excision line marked with two wires. Final reply to be given after the analysis of paraffin specimens.

Assistant:

Pathologist:

Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Case is for		
Review of		
Date Received		

W 5/20/13
5/17/13

Source: NCI Genomic Data Commons file f394372b-389a-4088-a16f-dec944d46c67 (TCGA-D6-A6EN.74B52FEF-64A5-448E-9B3D-1C5364C190F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).